Somatic mutation profile of tumor specimen TCGA-MB-A5Y9-01A (aliquot TCGA-MB-A5Y9-01A-11D-A29N-09) from TCGA case TCGA-MB-A5Y9, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-MB-A5Y9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f94e1164-2098-4d24-bd84-4bb87cac5492.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MB-A5Y9-10A (Blood Derived Normal), aliquot TCGA-MB-A5Y9-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104c1e95-9bf9-4ba4-8e22-2b7ed55cc8da

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 17, Silent 4, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1_919+9del p.X307_splice | Splice Site (DEL) | VAF 21/90 reads (23%) | hotspot (GDC flag); called by mutect2, varscan2
- ADGRF4 | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99348185; called by muse, mutect2
- BRD2 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100875603; called by muse, mutect2
- C9orf152 | c.515T>A p.I172N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101272376; called by muse, mutect2, varscan2
- CEP95 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs200075663, COSV73609489; called by muse, mutect2
- CHRM5 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV67247321; called by muse, mutect2, varscan2
- DST | c.20044C>G p.L6682V (on ENST00000361203 / NM_001374722.1; = p.L4379V on NM_015548.5) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.226); catalogued as COSV99753497; called by muse, mutect2
- FAM47C | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as COSV100792412; called by muse, mutect2, varscan2
- FBXO42 | c.2015G>A p.G672E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100981696; called by muse, mutect2, varscan2
- GZF1 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100582453; called by muse, mutect2
- KCNH2 | c.1433C>A p.A478D | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as rs1181952959, COSV100059605; called by muse, mutect2
- OR2T2 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61618495; called by muse, mutect2, varscan2
- PCLO | c.14791+7G>C | Splice Region (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100429861; called by muse, mutect2
- PRKCB | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs563116744, COSV57805302; called by mutect2, varscan2
- TLL1 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV50278891; called by muse, mutect2, varscan2
- TSBP1 | c.844A>G p.K282E (on ENST00000617061; = p.K285E on NM_006781.5) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1192515863, COSV100898744; called by muse, mutect2, varscan2
- VCAM1 | c.1979T>C p.L660S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV99658356; called by muse, mutect2, varscan2
- ZNF488 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.294); catalogued as rs202233826; called by muse, mutect2
- APBA2 | c.1637T>A p.I546N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- CELSR2 | c.7609C>T p.L2537= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99603435; called by mutect2, varscan2
- PCDHA5 | c.1362C>T p.F454= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs536422534, COSV100972196; called by muse, mutect2, varscan2
- PCDHA6 | c.1824G>A p.S608= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2
- PKN1 | c.2487C>T p.N829= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs367563299; called by muse, mutect2, varscan2
